Somatic mutation profile of tumor specimen TCGA-EJ-7784-01A (aliquot TCGA-EJ-7784-01A-11D-2114-08) from TCGA case TCGA-EJ-7784, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.5 years (23,183 days).
Specimen TCGA-EJ-7784-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65eada60-ee3c-4e3e-a461-311edd5ea17e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7784-10A (Blood Derived Normal), aliquot TCGA-EJ-7784-10A-01D-2114-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/691dfec5-ebf4-4e56-934c-274ee1e1c787

The open-access MAF lists 34 somatic variants for this specimen: 29 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 4, Frame Shift Ins 3, Nonsense Mutation 2, Frame Shift Del 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL6B | c.551T>A p.V184D | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50513988; called by muse, mutect2
- ACTL7B | c.955A>G p.T319A | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs1269202919, COSV65926942; called by muse, mutect2, varscan2
- C6orf62 | c.389C>G p.S130C | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1220898270, COSV65290242; called by muse, mutect2, varscan2
- CDK12 | c.4337G>A p.G1446E (on ENST00000447079 / NM_016507.4; = p.G1437E on NM_015083.3) | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as COSV70999579; called by muse, mutect2, varscan2
- CRY2 | c.17C>G p.A6G | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs752759191, COSV69888210; called by muse, mutect2
- CXCR2 | c.313G>C p.A105P | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59279908; called by muse, mutect2, varscan2
- DNAH9 | c.1612C>A p.P538T | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV52338338; called by muse, mutect2, varscan2
- DUS3L | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs545783379, COSV57831306; called by muse, varscan2
- FAM47A | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV60494534; called by muse, mutect2, varscan2
- IGSF10 | c.3901A>G p.I1301V | Missense Mutation (SNP) | VAF 89/187 reads (48%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV56782435; called by muse, mutect2, varscan2
- KPRP | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 89/278 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as COSV64221120, COSV64222505; called by muse, mutect2, varscan2
- METTL14 | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as CM142483, COSV66310188; called by muse, mutect2, varscan2
- MLF2 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV52570778; called by muse, mutect2, varscan2
- MMACHC | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs751530925, COSV53113136; called by muse, mutect2
- OR10K1 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs185874732; called by muse, mutect2, varscan2
- OR5D16 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as rs542655306, COSV65721423; called by muse, mutect2, varscan2
- OTOP1 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs1203270021, COSV56390586; called by muse, mutect2, varscan2
- PASK | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs199606444, COSV52149738; called by muse, mutect2
- PTGS1 | c.1640G>A p.S547N | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56290570; called by muse, mutect2
- RYR2 | c.4078G>T p.D1360Y | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV63668351; called by muse, mutect2, varscan2
- SUPT16H | c.1991A>T p.D664V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53522743; called by muse, mutect2, varscan2
- UBR1 | c.5026G>C p.V1676L | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (1); PolyPhen probably damaging (0.987); catalogued as COSV51927148; called by muse, mutect2
- WNT5A | c.677G>A p.G226D | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52836537; called by muse, mutect2, varscan2
- ZDHHC16 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs151287328; called by muse, mutect2, varscan2
- ZNF597 | c.161-2A>C p.X54_splice | Splice Site (SNP) | VAF 14/46 reads (30%) | catalogued as COSV57083737; called by muse, mutect2, varscan2
- DNAH8 | c.8838dup p.H2947Tfs*11 | Frame Shift Ins (INS) | VAF 8/41 reads (20%) | called by mutect2, pindel
- DNASE2B | c.892dup p.Y298Lfs*61 | Frame Shift Ins (INS) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- NEB | c.5152del p.Q1718Sfs*6 | Frame Shift Del (DEL) | VAF 18/39 reads (46%) | called by mutect2, pindel, varscan2
- PLA2R1 | c.2822dup p.V942Gfs*25 | Frame Shift Ins (INS) | VAF 26/51 reads (51%) | called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.3570T>A p.G1190= | Silent (SNP) | VAF 8/150 reads (5%) | catalogued as COSV51841848; called by muse, mutect2
- DNAJB11 | c.579C>T p.C193= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as rs759619633, COSV54002018; called by muse, mutect2
- MRPL19 | c.345T>C p.S115= | Silent (SNP) | VAF 73/146 reads (50%) | catalogued as COSV62566641; called by muse, mutect2, varscan2
- XRCC4 | c.537G>T p.R179= | Silent (SNP) | VAF 11/113 reads (10%) | catalogued as rs1217531558, COSV56533967; called by muse, mutect2, varscan2
- SSPOP | n.6199G>A | RNA (SNP) | VAF 32/64 reads (50%) | catalogued as COSV50486683; called by muse, mutect2, varscan2
